Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AALF, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AALF-01A (Primary Tumor).

Concerning

Summary pathology report

Left orchidectomy; nonseminoma (YST 100%); diameter 9 cm; no angio-invasion; no invasion of rete testis; tumor confined to testis.

Date of procurement (= date of orchidectomy):

ICD O-3

Tumor, yolk sac 907113
Site of Tumor NOS C62.9
Q10 3/5/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file a795b85f-587b-47d5-8f66-f10153dbf95c (TCGA-2G-AALF.E1681A1A-F6BE-45C6-A3BA-546B96F61495.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).